MMRF case MMRF_1489 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/ce2d88e3-4ab5-427e-9bd9-98e3c96036f2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 72 years; Vital status: Dead; Days to death: 390 days (1.1 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.7 years (26,551 days); ISS stage: III; Days to last known disease status: 390 days (1.1 years); Days to last follow up: 390 days (1.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 334 days; Days to treatment end: 343 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 357 days; Days to treatment end: 357 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 358 days; Days to treatment end: 358 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 390.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 1): M Protein 2.91 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 69.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.32 mg/dL; Immunoglobulin G 46.4 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 9.49 µg/mL; Lactate Dehydrogenase 1.95 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 35 g/L; Total Protein 8.8 g/dL; Glucose 5.45 mmol/L.
- Day 79 (ECOG 2): M Protein 1.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.08 mg/dL; Immunoglobulin G 17.5 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 212 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 9.64 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.7 g/dL; Glucose 3.74 mmol/L.
- Day 254 (ECOG 2): M Protein 0.69 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 13 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 5.87 µg/mL; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 120 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.33 mmol/L; Albumin 36 g/L; Total Protein 6.1 g/dL; Glucose 6.71 mmol/L.
- Day 358 (ECOG 2): M Protein 0.84 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 12.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.27 mg/dL; Immunoglobulin G 14.8 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 7.15 µg/mL; Lactate Dehydrogenase 6.32 µkat/L; Hemoglobin 6.76 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 3.58 ×10⁹/L; Platelets 196 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.23 mmol/L; Albumin 29 g/L; Total Protein 6.2 g/dL; Glucose 7.37 mmol/L.

Other clinical attributes
- Day -16: Weight: 79 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_1489_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_1489_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
